Somatic mutation profile of tumor specimen TCGA-ET-A3DS-01A (aliquot TCGA-ET-A3DS-01A-11D-A19J-08) from TCGA case TCGA-ET-A3DS, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 33.5 years (12,252 days).
Specimen TCGA-ET-A3DS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec359ef8-a68c-4cfc-9e44-b1f4fd1578f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3DS-10A (Blood Derived Normal), aliquot TCGA-ET-A3DS-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98977660-fd64-44b3-90f4-09bd09a0ccc8

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 5 silent.
By variant classification: Silent 5, Missense Mutation 4, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC62 | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53437888; called by muse, mutect2, varscan2
- LRSAM1 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as COSV55943216; called by muse, mutect2, varscan2
- QSER1 | c.662T>G p.V221G (on ENST00000399302; = p.V350G on NM_001076786.3) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV67902014; called by muse, mutect2, varscan2
- SH3KBP1 | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.038); catalogued as rs369126109, COSV65650058; called by muse, mutect2, varscan2
- HNRNPC | c.779_780del p.S260Cfs*2 (on ENST00000420743; = p.S247Cfs*2 on NM_004500.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/84 reads (21%) | called by pindel, varscan2
- ADGRG4 | c.1329C>T p.A443= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs749064564, COSV54953939, COSV54964276; called by muse, mutect2, varscan2
- BTAF1 | c.2499T>C p.S833= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs1315582651, COSV56440491; called by muse, mutect2, varscan2
- GOLGB1 | c.3735C>T p.D1245= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs759460081, COSV61464925; called by muse, mutect2, varscan2
- KCNAB3 | c.438C>T p.S146= | Silent (SNP) | VAF 12/160 reads (8%) | catalogued as COSV58051665; called by muse, mutect2
- TSHR | c.1407C>A p.L469= | Silent (SNP) | VAF 44/119 reads (37%) | catalogued as COSV53334097; called by muse, mutect2, varscan2
